Somatic mutation profile of tumor specimen TARGET-10-PARDHK-09A (aliquot TARGET-10-PARDHK-09A-01D) from TARGET case TARGET-10-PARDHK, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.8 years (641 days).
Specimen TARGET-10-PARDHK-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eedb17fa-f28f-4308-aef6-71e747972acd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARDHK-10A (Blood Derived Normal), aliquot TARGET-10-PARDHK-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/97e4c93d-8672-40ed-b2a1-6f468655d460

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 2, In Frame Del 1, 3'UTR 1, Intron 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCL6 | c.1754G>A p.R585Q | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.28); catalogued as COSV99215751; called by muse, mutect2, varscan2
- KCNJ4 | c.392C>T p.T131M | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57856056; called by muse, mutect2, varscan2
- KLHDC10 | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs576518672; called by muse, mutect2, varscan2
- SLITRK4 | c.2182G>A p.E728K | Missense Mutation (SNP) | VAF 38/328 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV100567458; called by muse, mutect2, varscan2
- USP19 | c.173C>T p.S58L | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as rs1414836558; called by muse, mutect2
- ACADM | c.57_64delinsCC p.W20_S22delinsP | In Frame Del (DEL) | VAF 21/97 reads (22%) | called by pindel, varscan2*
- CCDC158 | c.2462C>T p.A821V | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- DMD | c.1813-2A>G p.X605_splice | Splice Site (SNP) | VAF 38/96 reads (40%) | called by muse, mutect2, varscan2
- ELF1 | c.777G>A p.M259I | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SFMBT2 | c.1654C>G p.P552A | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PTPN14 | c.114G>A p.S38= | Silent (SNP) | VAF 8/156 reads (5%) | catalogued as rs911944907, COSV65282923; called by muse, mutect2
- RPLP2 | c.138G>C p.L46= | Silent (SNP) | VAF 11/103 reads (11%) | catalogued as rs778708486; called by muse, mutect2, varscan2
- MIR4328 | n.3C>G | RNA (SNP) | VAF 37/130 reads (28%) | called by muse, mutect2, varscan2
- MREG | c.*1492C>T | 3'UTR (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
- TJP2 | c.61-7302G>A | Intron (SNP) | VAF 26/58 reads (45%) | called by muse, mutect2, varscan2
